CCDI case PBCLEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/bc4fae7c-1f27-4a44-a7c4-ffebfc34311b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 3.8 years (1,403 days).

Biospecimens (3 samples)
- Samples 0DVVIB, 0DVVLC (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVVMA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
